Somatic mutation profile of tumor specimen BLGSP-71-06-00091-01A (aliquot BLGSP-71-06-00091-01A-11D-A663-33) from CGCI case BLGSP-71-06-00091, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 7.2 years (2,619 days).
Specimen BLGSP-71-06-00091-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Mandible; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20125336-4780-41ea-9939-ee94b694123c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-06-00091-99A (Granulocytes), aliquot BLGSP-71-06-00091-99A-01D-A663-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4878876b-adde-4973-ad5e-f6cb2b19c121

The open-access MAF lists 11 somatic variants for this specimen: 4 protein-altering or splice-affecting, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'Flank 3, Intron 2, 5'UTR 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC072022.2 | c.91A>C p.N31H | Missense Mutation (SNP) | VAF 68/210 reads (32%) | catalogued as COSV69205784, COSV69207018; called by muse, varscan2
- ID3 | c.300+1G>A p.X100_splice | Splice Site (SNP) | VAF 23/71 reads (32%) | catalogued as COSV65801120; called by muse, varscan2
- ID3 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1055074154, COSV65800845, COSV65801501; called by muse, varscan2
- NRK | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AC072022.2 | c.-256C>G | 5'UTR (SNP) | VAF 27/138 reads (20%) | called by muse, mutect2, varscan2
- BCL6 | chr3:187745469 A>G | 5'Flank (SNP) | VAF 76/270 reads (28%) | catalogued as rs59191539, COSV69205689; called by muse, varscan2
- BCL6 | chr3:187745487 A>C | 5'Flank (SNP) | VAF 66/263 reads (25%) | catalogued as COSV69207539; called by muse, varscan2
- CXCR4 | c.15+323T>G | Intron (SNP) | VAF 34/158 reads (22%) | called by muse, varscan2
- PIM1 | c.-125G>A | 5'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, varscan2
- RFTN1 | c.-9+558G>A | Intron (SNP) | VAF 28/101 reads (28%) | catalogued as rs560800551; called by muse, mutect2, varscan2
- TMSB4X | chrX:12975602 T>C | 5'Flank (SNP) | VAF 18/70 reads (26%) | catalogued as rs971342432; called by muse, mutect2, varscan2
